Somatic mutation profile of tumor specimen BA3151D (aliquot aq-BA3151D) from BEATAML1.0 case 2656, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.4 years (19,502 days).
Specimen BA3151D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e96d2cfd-cc3b-4646-837e-574938b0ecb4.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3279D (Solid Tissue Normal), aliquot aq-BA3279D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bcbbc11c-6a8f-4658-8015-3078fe7b5efc

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYO5B | c.3397G>A p.E1133K | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV53210513; called by muse, mutect2, varscan2
- PCSK5 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767412291, COSV65088213; called by muse, mutect2, varscan2
- SLITRK3 | c.937A>G p.M313V | Missense Mutation (SNP) | VAF 14/361 reads (4%) | SIFT tolerated (0.67); PolyPhen benign (0.011); catalogued as rs1195136525; called by muse, mutect2
- ZNF248 | c.1658G>A p.C553Y | Missense Mutation (SNP) | VAF 124/436 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GABRG2 | c.1095G>A p.S365= (on ENST00000361925 / NM_001375343.1; = p.S325= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/119 reads (39%) | catalogued as rs774809218; ClinVar: likely benign; called by muse, mutect2, varscan2
